Somatic mutation profile of tumor specimen TCGA-A3-3326-01A (aliquot TCGA-A3-3326-01A-01D-0966-08) from TCGA case TCGA-A3-3326, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 47.3 years (17,285 days).
Specimen TCGA-A3-3326-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87b8aeba-c6e6-462b-a93a-e1472689a197.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3326-11A (Solid Tissue Normal), aliquot TCGA-A3-3326-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89c9c509-9be1-4999-a5cc-17782ae99e17

The open-access MAF lists 58 somatic variants for this specimen: 40 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 26, Silent 18, Frame Shift Del 8, Nonsense Mutation 3, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS4B | c.495C>G p.Y165* | Nonsense Mutation (SNP) | VAF 32/135 reads (24%) | catalogued as COSV61139651; called by muse, mutect2, varscan2
- AOC1 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV62869764; called by muse, mutect2, varscan2
- BACH1 | c.1985G>T p.G662V | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as COSV54519822; called by muse, mutect2, varscan2
- BSN | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs752273895, COSV56522483; called by muse, mutect2, varscan2
- CACNA1D | c.6283A>G p.T2095A (on ENST00000350061 / NM_001128840.3; = p.T2115A on NM_000720.4) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as COSV55455433; called by muse, mutect2
- CDH10 | c.1785G>A p.M595I | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as rs1448055370, COSV52577259, COSV52587943; called by muse, mutect2, varscan2
- CHST4 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs759388461, COSV58297683; called by muse, mutect2, varscan2
- CNTNAP1 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV52852251; called by muse, mutect2, varscan2
- COL4A3 | c.4933C>T p.P1645S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67417232; called by muse, mutect2, varscan2
- FAM135B | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.954); catalogued as COSV52738538; called by muse, mutect2, varscan2
- FCRL2 | c.1394-1G>T p.X465_splice | Splice Site (SNP) | VAF 13/176 reads (7%) | catalogued as COSV63834273; called by muse, mutect2
- GON4L | c.6497C>G p.T2166S | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55197775; called by muse, mutect2, varscan2
- GTF3C1 | c.3722G>T p.S1241I | Missense Mutation (SNP) | VAF 117/452 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV62242759; called by muse, mutect2, varscan2
- INSC | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as COSV65411692; called by muse, mutect2, varscan2
- JHY | c.1007A>T p.E336V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV57077478; called by muse, mutect2
- KDM3B | c.350G>T p.W117L | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58692759; called by muse, mutect2, varscan2
- KPNA1 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 123/472 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60270135; called by muse, mutect2, varscan2
- LAMA1 | c.7000A>T p.N2334Y | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV67539990; called by muse, mutect2, varscan2
- ME1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63840749; called by muse, mutect2, varscan2
- ME2 | c.321A>C p.L107F | Missense Mutation (SNP) | VAF 87/397 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.113); catalogued as rs752119715, COSV58424138; called by muse, mutect2, varscan2
- MS4A3 | c.616-1G>A p.X206_splice | Splice Site (SNP) | VAF 34/160 reads (21%) | catalogued as COSV53936956; called by muse, mutect2, varscan2
- NAA60 | c.523T>C p.F175L | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV62655333; called by muse, mutect2, varscan2
- NAA60 | c.524T>A p.F175Y | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV62655368; called by muse, mutect2, varscan2
- PAPPA2 | c.2164T>C p.Y722H | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62781747; called by muse, mutect2, varscan2
- PBRM1 | c.4006del p.V1336Sfs*48 (on ENST00000296302 / NM_001366071.2; = p.X1310_splice on NM_018313.5) | Frame Shift Del (DEL) | VAF 46/124 reads (37%) | catalogued as COSV56261841; called by mutect2, pindel, varscan2
- PCK1 | c.677del p.R226Kfs*41 | Frame Shift Del (DEL) | VAF 43/162 reads (27%) | catalogued as COSV60129665; called by mutect2, pindel, varscan2
- PML | c.1986C>G p.F662L | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV51449863; called by muse, mutect2, varscan2
- SMCR8 | c.83A>G p.E28G | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58179188; called by muse, mutect2, varscan2
- TMEM181 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.093); catalogued as COSV65564544; called by muse, mutect2, varscan2
- TRPV6 | c.1325T>C p.V442A | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV63892571; called by muse, mutect2, varscan2
- VHL | c.468T>A p.Y156* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as CM961429, COSV56555576, COSV56562965; called by muse, mutect2, varscan2
- WT1 | c.1024T>A p.Y342N | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV60070383, COSV60076178, COSV99070050; called by muse, mutect2, varscan2
- ZNF773 | c.574A>T p.K192* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV56589345; called by muse, mutect2, varscan2
- AGMO | c.1221del p.H408Tfs*2 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- AMOTL1 | c.2072del p.Y691Sfs*12 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- COL5A2 | c.2077_2081del p.G693Sfs*16 | Frame Shift Del (DEL) | VAF 31/131 reads (24%) | called by mutect2, pindel, varscan2
- LCE1E | c.338_340del p.H113_S114delinsP | In Frame Del (DEL) | VAF 42/211 reads (20%) | called by mutect2, pindel, varscan2
- NRSN1 | c.294del p.F98Lfs*38 | Frame Shift Del (DEL) | VAF 53/208 reads (25%) | called by mutect2, pindel, varscan2
- RPL10A | c.249_252del p.H84Wfs*6 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.5468_5474del p.S1823Wfs*15 | Frame Shift Del (DEL) | VAF 51/215 reads (24%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.5097G>A p.K1699= (on ENST00000310343 / NM_001378025.1; = p.K1350= on NM_014715.4) | Silent (SNP) | VAF 51/222 reads (23%) | catalogued as COSV59851520; called by muse, mutect2, varscan2
- BLK | c.723C>G p.L241= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV52053865; called by muse, mutect2, varscan2
- BTF3L4 | c.462G>A p.K154= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as COSV57630446; called by muse, mutect2, varscan2
- CACNG4 | c.336C>T p.I112= | Silent (SNP) | VAF 50/224 reads (22%) | catalogued as rs1366760534, COSV50926103; called by muse, mutect2, varscan2
- CD22 | c.513G>T p.P171= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as COSV50058673; called by muse, mutect2, varscan2
- CTCFL | c.139T>C p.L47= | Silent (SNP) | VAF 152/560 reads (27%) | catalogued as rs1383753639, COSV54776606; called by muse, mutect2
- DCST2 | c.1911C>T p.T637= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV55052999; called by muse, mutect2, varscan2
- EEF1A1 | c.474T>C p.T158= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as rs1267099385, COSV100303394; called by muse, mutect2, varscan2
- FAT2 | c.2703A>G p.K901= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as COSV55824303; called by muse, mutect2, varscan2
- HSPA8 | c.633T>C p.T211= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as rs756568266, COSV57084719; called by muse, mutect2, varscan2
- MKS1 | c.1185T>C p.P395= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV56597898; called by muse, mutect2, varscan2
- MYH15 | c.957C>G p.P319= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV56314532, COSV99841924; called by muse, mutect2, varscan2
- NGLY1 | c.66G>A p.Q22= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV54988235; called by muse, mutect2, varscan2
- TBCC | c.9C>T p.S3= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs537953279, COSV55130640; called by muse, mutect2, varscan2
- TTN | c.18126T>C p.S6042= (on ENST00000591111; = p.S5115= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV60183929; called by muse, mutect2, varscan2
- UBR4 | c.2208A>G p.G736= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV64393967; called by muse, mutect2, varscan2
- ZFP91 | c.1431C>A p.G477= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV60160423; called by muse, mutect2, varscan2
- ZNF425 | c.969G>C p.L323= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV65201850; called by muse, mutect2, varscan2
